Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A3-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Right lobe liver (1,775 grams, 22 x 17 x 10 cm) and gallbladder (8.2 x 3.3 x 1.3 cm)

A1, B1, B2, B3, B4, B5, B6, B7, B8, B9, B10

DIAGNOSIS:

Liver, right lobe, resection: Invasive grade 2 (of 4) hepatocellular carcinoma forming a 19 x 11.5 x 9 cm mass with extension into the inferior vena cava. Tumor extends to within 5 mm of the nearest surgical margin which is negative. One periportal lymph node is negative for tumor.

Gallbladder, cholecystectomy: Chronic cholecystitis.

PHOTOGRAPHED IN LAB

ICD-O-3

carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0

lu
9/22/11

Diagnostic Discrepancy		X

lu 9/22/11

Source: NCI Genomic Data Commons file 84c73941-9922-4077-861a-4bf00db3dc59 (TCGA-DD-A3A3.A37A1F44-D2AD-457C-8292-3E7A6667268D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).